Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3489, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3489-01A (Primary Tumor).

*** Diagnosis / Diagnoses: ***

24-cm-long resection of the colon under inclusion of a poorly differentiated, largely ulcerated adenocarcinoma, of a maximum of 3.5 cm in diameter and of the colorectal type, with infiltration of the pericolic fatty tissue (pT3; G3). Tumor-free resection margins of the colon. Three tubular adenomas in the colonic mucosa with low- to moderate-grade dysplasia in the remainder.

A follow-up report will be made on the lymph node status.

Follow-up report:

A total of 28 histologically tumor-free lymph nodes of a maximum of 0.8 cm in diameter were determined after acetone fixation.

Final tumor stage: pT3 pN0 (0/28) pMX; G3

Source: NCI Genomic Data Commons file 6f2217de-3c7d-4404-b8d2-6d7e694e979d (TCGA-AA-3489.FCC3F802-40C7-4BCB-9F32-49BB1BBB7BB2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).